Somatic mutation profile of tumor specimen ALCH-B2MV-TTP1-A (aliquot ALCH-B2MV-TTP1-A-1-0-D-A77P-36) from ALCHEMIST case ALCH-B2MV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.7 years (23,637 days).
Specimen ALCH-B2MV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02ca9c08-fb44-4447-a379-2ab5bfb51748.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2MV-NB1-A (Blood Derived Normal), aliquot ALCH-B2MV-NB1-A-2-0-D-A77P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15e5dcc7-6b4c-4965-b9bb-baf0fac1d96f

The open-access MAF lists 28 somatic variants for this specimen: 13 protein-altering or splice-affecting, 9 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 9, 5'Flank 2, Intron 2, RNA 1, In Frame Del 1, Nonsense Mutation 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 20/186 reads (11%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- EGF | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 29/252 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as rs373552129; called by muse, mutect2, varscan2
- HDAC9 | c.2027A>T p.K676I | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as rs1476157677; called by muse, mutect2, varscan2
- CNIH2 | c.150+3A>G | Splice Region (SNP) | VAF 9/87 reads (10%) | called by muse, mutect2, varscan2
- DGKI | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LIN7C | c.209G>A p.R70K | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2
- MUC17 | c.11791G>T p.E3931* | Nonsense Mutation (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- PLD5 | c.193C>A p.Q65K (on ENST00000442594; = p.Q3K on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- PRRC2B | c.4465T>C p.S1489P | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); called by muse, mutect2
- RAB11FIP1 | c.1795T>C p.S599P | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.027); called by muse, mutect2
- SLCO6A1 | c.2111T>C p.V704A | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2
- TAC3 | c.341T>A p.L114H | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); called by muse, mutect2
- TMTC4 | c.1969T>G p.S657A (on ENST00000376234 / NM_001350577.2; = p.S676A on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- HUWE1 | c.11958A>G p.V3986= | Silent (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
- KLF10 | c.798A>G p.G266= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV53435901; called by muse, mutect2
- LRRC74B | c.852C>T p.N284= | Silent (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- MCM8 | c.1023A>G p.E341= | Silent (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2
- MSLNL | c.1614C>T p.F538= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs1037082805; called by muse, varscan2
- NRDE2 | c.1077G>A p.L359= | Silent (SNP) | VAF 5/91 reads (5%) | called by muse, mutect2
- OR2M3 | c.414T>A p.P138= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV71759112; called by muse, mutect2, varscan2
- SPDYE4 | c.150C>A p.G50= | Silent (SNP) | VAF 4/25 reads (16%) | called by muse, varscan2
- ZNF497 | c.540C>T p.H180= | Silent (SNP) | VAF 3/21 reads (14%) | called by muse, varscan2
- EHMT2 | chr6:31901131 G>A | 5'Flank (SNP) | VAF 4/56 reads (7%) | catalogued as COSV64994040; called by muse, mutect2
- FOXRED1 | chr11:126269150 C>T | 5'Flank (SNP) | VAF 8/77 reads (10%) | called by muse, mutect2, varscan2
- OR2M1P | n.426A>G | RNA (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- RARA | c.179-6851G>A | Intron (SNP) | VAF 13/61 reads (21%) | catalogued as rs1416023336; called by muse, mutect2, varscan2
- SETD4 | c.74-206G>T | Intron (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- SLITRK2 | chrX:145827851 T>A | 3'Flank (SNP) | VAF 18/230 reads (8%) | catalogued as rs1157526167; called by muse, mutect2
